Somatic mutation profile of tumor specimen 0DWVGO from CCDI case PBCPJI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ewing sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 17.3 years (6,335 days).
Specimen 0DWVGO: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3216553d-5c9c-4221-8759-a8d1c90fc514.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWVEJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/556c8541-1d3d-4790-bcd3-303b40603867

The open-access MAF lists 19 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 5, 3'UTR 3, Intron 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C8orf58 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 42/408 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.866); catalogued as COSV51515710; called by muse, mutect2
- COL11A2 | c.1658G>T p.G553V (on ENST00000341947 / NM_080680.3; = p.G446V on NM_080679.2) | Missense Mutation (SNP) | VAF 112/295 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780499630; called by muse, mutect2, varscan2
- KRT34 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 56/644 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.158); catalogued as rs1437522947; called by muse, mutect2
- NPRL3 | c.1330G>A p.A444T (on ENST00000611875 / NM_001077350.3; = p.A419T on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/274 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as rs368198378; called by muse, mutect2, varscan2
- MGAM2 | c.189T>A p.D63E | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.96); PolyPhen benign (0.024); called by muse, mutect2
- OR10J5 | c.659T>C p.V220A | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.217); called by muse, mutect2
- UEVLD | c.1154A>G p.Q385R | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2
- UGT8 | c.324T>A p.D108E | Missense Mutation (SNP) | VAF 142/347 reads (41%) | SIFT tolerated (0.9); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- FSIP2 | c.5202G>A p.A1734= | Silent (SNP) | VAF 26/385 reads (7%) | catalogued as rs568599074, COSV58084044; called by muse, mutect2
- PGK2 | c.303C>T p.G101= | Silent (SNP) | VAF 137/316 reads (43%) | catalogued as rs549102825, COSV59163718; called by muse, mutect2, varscan2
- WFDC3 | c.381C>T p.P127= | Silent (SNP) | VAF 30/408 reads (7%) | catalogued as rs1377207451; called by muse, mutect2
- ZMYND8 | c.2259C>G p.G753= (on ENST00000311275 / NM_001363741.2; = p.G773= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/450 reads (6%) | called by muse, mutect2
- ZNF551 | c.165C>T p.C55= | Silent (SNP) | VAF 23/325 reads (7%) | catalogued as rs1319321859; called by muse, mutect2
- ACAP1 | c.1852-13C>A | Intron (SNP) | VAF 15/115 reads (13%) | called by muse, mutect2, varscan2
- BMI1 | c.*97C>G | 3'UTR (SNP) | VAF 36/67 reads (54%) | catalogued as rs983949228; called by muse, mutect2, varscan2
- CTBP1 | c.893+11G>A | Intron (SNP) | VAF 18/228 reads (8%) | catalogued as rs772651450; called by muse, mutect2
- CYSLTR1 | c.*22A>C | 3'UTR (SNP) | VAF 138/142 reads (97%) | catalogued as COSV100964716, COSV100964739; called by muse, mutect2
- MROH8 | c.370+2521C>A | Intron (SNP) | VAF 114/430 reads (27%) | called by muse, mutect2
- TP63 | c.*16C>A | 3'UTR (SNP) | VAF 16/188 reads (9%) | catalogued as COSV99286549; called by muse, mutect2
